Somatic mutation profile of tumor specimen C3L-00766-01 (aliquot CPT0025170009) from CPTAC case C3L-00766, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.2 years (20,879 days).
Specimen C3L-00766-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45486ce7-7b91-477c-be13-7c95e2451a62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00766-32 (Blood Derived Normal), aliquot CPT0029430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/300eaa1f-5617-46e6-8391-4857eb46118f

The open-access MAF lists 34 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Intron 3, Nonsense Mutation 2, 3'UTR 2, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL36RN | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs867788898; called by muse, mutect2
- IQSEC2 | c.1637G>C p.W546S (on ENST00000642864 / NM_001111125.3; = p.W341S on NM_015075.2) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV64724127; called by muse, mutect2
- MTERF4 | c.16C>A p.R6S | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.989); catalogued as rs770916374, COSV99299273; called by muse, mutect2
- UNC93B1 | c.816C>A p.N272K | Missense Mutation (SNP) | VAF 32/337 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1242998312; called by muse, mutect2
- BIRC6 | c.1930A>T p.K644* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- CLDN34 | c.350G>C p.R117T | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.089); called by muse, mutect2
- DNHD1 | c.7751A>T p.H2584L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.197); called by muse, mutect2
- GPR139 | c.334A>C p.I112L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); called by muse, mutect2
- HERC6 | c.3023T>A p.I1008N | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPM | c.2186del p.N729Tfs*32 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel
- PIEZO1 | c.3121T>A p.Y1041N | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SON | c.4367A>G p.E1456G | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2
- SORL1 | c.46T>A p.F16I | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- STK16 | c.44T>A p.I15N | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SYNE2 | c.15518C>T p.T5173I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TENM3 | c.5497dup p.Q1833Pfs*6 | Frame Shift Ins (INS) | VAF 28/304 reads (9%) | called by mutect2, pindel
- TRIM64C | c.40A>C p.I14L | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.32); called by muse, mutect2
- TUBB2A | c.598T>A p.Y200N | Missense Mutation (SNP) | VAF 56/590 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- UNC93B1 | c.817A>T p.K273* | Nonsense Mutation (SNP) | VAF 32/338 reads (9%) | called by muse, mutect2
- ZNF627 | c.452A>G p.H151R | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- AKAP3 | c.1908T>C p.S636= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- AP002748.5 | c.279A>C p.V93= | Silent (SNP) | VAF 24/249 reads (10%) | called by muse, mutect2, varscan2
- CD80 | c.480A>T p.I160= | Silent (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- HSD11B1L | c.171G>A p.V57= | Silent (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- KLHL25 | c.1566G>T p.G522= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- KRTAP10-9 | c.207A>T p.S69= | Silent (SNP) | VAF 62/570 reads (11%) | called by muse, mutect2, varscan2
- SPTLC2 | c.891T>G p.V297= | Silent (SNP) | VAF 21/209 reads (10%) | called by muse, mutect2, varscan2
- TMEM51 | c.660C>G p.L220= | Silent (SNP) | VAF 22/226 reads (10%) | called by muse, mutect2
- AASS | c.*13T>G | 3'UTR (SNP) | VAF 29/168 reads (17%) | catalogued as rs1372051496; called by muse, varscan2
- ABAT | c.-41-21844T>C | Intron (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- AMFR | c.*609T>A | 3'UTR (SNP) | VAF 14/185 reads (8%) | called by muse, mutect2
- ANK3 | c.12596-540C>A | Intron (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- HNRNPA3 | c.739+33C>T | Intron (SNP) | VAF 14/162 reads (9%) | catalogued as rs1558969732; called by muse, mutect2
- NPC2 | c.-17G>T | 5'UTR (SNP) | VAF 37/375 reads (10%) | called by muse, mutect2
